Somatic mutation profile of tumor specimen TCGA-A2-A0EV-01A (aliquot TCGA-A2-A0EV-01A-11W-A050-09) from TCGA case TCGA-A2-A0EV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 80.2 years (29,285 days).
Specimen TCGA-A2-A0EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1444baeb-6856-4d7e-97d5-cd29233867d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EV-10A (Blood Derived Normal), aliquot TCGA-A2-A0EV-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61f805bf-0629-4c69-be02-49c0e8e9ca0e

The open-access MAF lists 63 somatic variants for this specimen: 52 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 82/137 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 35/81 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP1G1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55485451; called by muse, mutect2, varscan2
- ARHGAP35 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs376792949; called by muse, mutect2, varscan2
- C3orf52 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV53494666; called by muse, mutect2, varscan2
- CACUL1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100432716, COSV60993115; called by muse, mutect2, varscan2
- CASP8 | c.499A>C p.I167L (on ENST00000432109 / NM_033355.3; = p.I199L on NM_001228.4) | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV51845260; called by muse, mutect2, varscan2
- CCNG2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs558158350, COSV60353075; called by muse, mutect2, varscan2
- CELA3B | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369079072; called by muse, mutect2, varscan2
- CES5A | c.1544C>T p.T515I (on ENST00000290567 / NM_001143685.2; = p.T465I on NM_145024.3) | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV99307096; called by muse, mutect2
- CLASP1 | c.2725C>T p.H909Y | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV55313935; called by muse, mutect2, varscan2
- CLEC16A | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as rs750171153, COSV68497863; called by muse, mutect2, varscan2
- CLEC6A | c.369+2T>C p.X123_splice | Splice Site (SNP) | VAF 25/96 reads (26%) | catalogued as COSV65986664; called by muse, mutect2, varscan2
- CRX | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1183477519, COSV55757006; called by muse, mutect2, varscan2
- DCLRE1C | c.1484G>C p.R495T (on ENST00000378278 / NM_001350965.2; = p.R380T on NM_022487.4) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV57952465; called by muse, mutect2, varscan2
- DGKG | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs772015690, COSV53961577; called by muse, mutect2, varscan2
- ESAM | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV54033340; called by muse, mutect2, varscan2
- EVA1C | c.843G>C p.Q281H | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV55822793; called by muse, mutect2, varscan2
- FARP2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs777159772, COSV50869001, COSV50876690; called by muse, mutect2, varscan2
- FBN3 | c.3605A>C p.E1202A | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV99559815; called by muse, mutect2
- GIMAP7 | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57958408; called by muse, mutect2, varscan2
- GNPDA1 | c.361T>A p.F121I | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV60942873; called by mutect2, varscan2
- HABP4 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 100/547 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1310614407, COSV64514599; called by muse, mutect2, varscan2
- HSPA8 | c.696T>G p.D232E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV57082544; called by muse, mutect2, varscan2
- HYLS1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54988630; called by muse, mutect2, varscan2
- LRPPRC | c.2065C>T p.L689F | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1302227495, COSV53234047; called by muse, mutect2, varscan2
- MYO10 | c.6078G>A p.V2026= | Splice Region (SNP) | VAF 13/76 reads (17%) | catalogued as COSV57016682; called by muse, mutect2, varscan2
- NCOR1 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV51960883; called by muse, mutect2, varscan2
- NEB | c.15974G>A p.R5325Q | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1487630736, COSV50809906; called by muse, mutect2, varscan2
- OR2L13 | c.707C>G p.A236G | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63547989, COSV63557359; called by muse, mutect2, varscan2
- OR6A2 | c.821A>G p.D274G | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV60264419; called by muse, mutect2, varscan2
- PCDHGA1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV65294890; called by muse, mutect2, varscan2
- PCP2 | c.292-1G>A p.X98_splice | Splice Site (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100222095, COSV60696716; called by muse, mutect2, varscan2
- RSF1 | c.1989A>C p.K663N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57836452; called by muse, mutect2, varscan2
- SPG11 | c.6256C>G p.L2086V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55990841; called by muse, mutect2, varscan2
- TESK2 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs1366181680, COSV59149215; called by muse, mutect2, varscan2
- TGIF2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs919908252, COSV65836234; called by muse, mutect2, varscan2
- TMCC3 | c.1379G>C p.C460S | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV54152169; called by muse, mutect2, varscan2
- TRAK1 | c.547G>T p.E183* (on ENST00000327628 / NM_001349247.2; = p.E125* on NM_014965.5) | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV58255535; called by muse, mutect2, varscan2
- UBE3B | c.2141T>C p.F714S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774422074, COSV55091124; called by muse, mutect2, varscan2
- USH2A | c.15299G>A p.G5100E | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56327551; called by muse, mutect2, varscan2
- VPS13A | c.2969A>T p.N990I | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV100652168, COSV62435237; called by muse, mutect2, varscan2
- XDH | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs61731081, COSV65146915; called by muse, mutect2, varscan2
- ZMYND8 | c.2375C>T p.P792L (on ENST00000311275 / NM_001363741.2; = p.P812L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV53682910; called by muse, mutect2, varscan2
- ZNF420 | c.921T>G p.Y307* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV58492589; called by muse, mutect2, varscan2
- ZRSR2 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.029); catalogued as COSV57064610; called by muse, mutect2
- ZSCAN5A | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV54223753; called by muse, varscan2
- ZSCAN5A | c.582G>C p.R194S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV54223764, COSV54225501; called by muse, mutect2, varscan2
- IGLV5-48 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OGDH | c.2847dup p.N950Qfs*3 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- PIK3CA | c.1406_1407insTAA p.E469delinsDK | Splice Region (INS) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- SLC6A20 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.186); called by muse, mutect2
- ABI3BP | c.735C>A p.I245= | Silent (SNP) | VAF 116/353 reads (33%) | catalogued as COSV52528291; called by muse, mutect2, varscan2
- ADAMTS9 | c.3951G>A p.R1317= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV55775014; called by muse, mutect2, varscan2
- ADCY1 | c.1785C>T p.V595= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs747756051, COSV52030041; called by muse, mutect2, varscan2
- AP2A2 | c.441C>T p.F147= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs761093838, COSV100172477; called by muse, mutect2
- FLRT1 | c.1224C>T p.S408= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99734648; called by muse, mutect2, varscan2
- HOXC4 | c.495G>C p.R165= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57697889; called by muse, mutect2, varscan2
- KCNAB2 | c.366C>T p.G122= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs2229005; called by muse, mutect2, varscan2
- SLC6A20 | c.999G>A p.L333= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- TRUB1 | c.216C>T p.F72= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs981976400, COSV100075930; called by muse, mutect2, varscan2
- UBA2 | c.1809C>T p.V603= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs545176184, COSV55827269; called by muse, varscan2
- ZBBX | c.1131G>A p.L377= | Silent (SNP) | VAF 36/263 reads (14%) | catalogued as COSV56782662; called by muse, mutect2, varscan2
